Somatic mutation profile of tumor specimen 285fed94-1495-448e-879b-b55de9 (aliquot 285fed94-1495-448e-879b-b55de9_D6) from CPTAC case 04OV033, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV.
Specimen 285fed94-1495-448e-879b-b55de9: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0a3142a-c931-4856-920c-c8966bb02027.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ecdf88ff-20cc-4cb8-992e-5de6ac (Blood Derived Normal), aliquot ecdf88ff-20cc-4cb8-992e-5de6ac_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea4846d4-f490-49a0-a5e0-ecf8b5e28031

The open-access MAF lists 122 somatic variants for this specimen: 88 protein-altering or splice-affecting, 23 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 23, Intron 8, Splice Site 5, Frame Shift Del 5, Splice Region 2, Nonsense Mutation 2, 3'UTR 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.3598C>T p.Q1200* | Nonsense Mutation (SNP) | VAF 110/265 reads (42%) | catalogued as rs62625307, CM980228; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 105/296 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV67139521; called by muse, mutect2, varscan2
- ANO2 | c.2479C>G p.R827G (on ENST00000356134 / NM_001278597.3; = p.R831G on NM_001278596.3) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1001453035; called by muse, mutect2, varscan2
- AP3M2 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.393); catalogued as rs370609185; called by muse, mutect2, varscan2
- APTX | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 107/445 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs747334007; ClinVar: likely benign; called by muse, mutect2, varscan2
- CISH | c.126C>A p.F42L (on ENST00000348721 / NM_145071.4; = p.F59L on NM_013324.6) | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.525); catalogued as COSV62295536; called by muse, mutect2
- COL6A5 | c.1803C>A p.N601K | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs995840552; called by muse, mutect2, varscan2
- DNAH17 | c.12918A>G p.E4306= | Splice Region (SNP) | VAF 8/174 reads (5%) | catalogued as rs1176216638; called by muse, mutect2
- ETV3 | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV63864630; called by muse, mutect2
- FREM1 | c.3807C>G p.I1269M | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as rs1171424607; called by muse, mutect2, varscan2
- GABRB3 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 126/430 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV59484870, COSV59487152; called by muse, mutect2, varscan2
- HOXD9 | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs767718803; called by muse, varscan2
- HSD17B4 | c.1364C>T p.A455V (on ENST00000414835 / NM_001199291.3; = p.A430V on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs1282621174; called by muse, mutect2, varscan2
- IGHG2 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 46/960 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs376858176; called by muse, mutect2
- LARP4B | c.1808C>A p.A603D | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV60219962; called by muse, mutect2, varscan2
- LRRC31 | c.931C>A p.H311N | Missense Mutation (SNP) | VAF 105/266 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV52980098; called by muse, mutect2, varscan2
- OPN3 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs777101745, COSV100086987, COSV59364065; called by muse, mutect2, varscan2
- OR5W2 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV60617959, COSV60618430; called by muse, mutect2, varscan2
- PC | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.57); catalogued as rs1464614105, COSV63081550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC23IP | c.1171A>G p.I391V | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.412); catalogued as rs1391583376; called by muse, mutect2, varscan2
- SI | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 39/900 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52304467; called by muse, mutect2
- TANC2 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 34/610 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67338091; called by muse, mutect2
- TENM1 | c.5555C>T p.T1852M | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV64425857; called by muse, mutect2
- TFB1M | c.619C>G p.R207G | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as rs769068618; called by muse, mutect2, varscan2
- TREH | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV99874190; called by muse, mutect2, varscan2
- ADRA1D | c.371_383del p.N124Rfs*9 | Frame Shift Del (DEL) | VAF 87/324 reads (27%) | called by mutect2, pindel, varscan2
- ARFGAP2 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 13/258 reads (5%) | called by muse, mutect2
- ARFGEF1 | c.3954T>A p.D1318E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ASIC3 | c.462_468delinsATGTCA p.H155Cfs*118 | Frame Shift Del (DEL) | VAF 47/182 reads (26%) | called by pindel, varscan2*
- C11orf16 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2
- C20orf144 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.199); called by muse, mutect2
- C5orf47 | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- C6 | c.2575_2594del p.K859Hfs*4 | Frame Shift Del (DEL) | VAF 31/238 reads (13%) | called by mutect2, pindel, varscan2
- CFAP61 | c.79A>T p.I27F | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CFAP74 | c.2960C>A p.T987N | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- CNOT4 | c.1314C>A p.N438K (on ENST00000315544 / NM_001190848.1; = p.N435K on NM_013316.4) | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- COL1A2 | c.2545T>C p.S849P | Missense Mutation (SNP) | VAF 11/321 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CTNNA2 | c.434A>T p.D145V | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP4 | c.580-4_598delinsTTGT p.X194_splice | Splice Site (DEL) | VAF 40/215 reads (19%) | called by pindel, varscan2*
- EBLN1 | c.237A>T p.L79F | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- EFNB2 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ENOX2 | c.999G>T p.E333D (on ENST00000338144 / NM_001382520.1; = p.E304D on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- EPHA3 | c.335T>A p.V112D | Missense Mutation (SNP) | VAF 18/440 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- ESCO2 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- EVI5 | c.51+1del p.X17_splice | Splice Site (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- FAM166A | c.264_271del p.H88Qfs*6 | Frame Shift Del (DEL) | VAF 95/299 reads (32%) | called by mutect2, varscan2
- FAM83A | c.481-1G>C p.X161_splice | Splice Site (SNP) | VAF 41/287 reads (14%) | called by muse, mutect2, varscan2
- GALNT18 | c.720G>C p.R240S | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.422); called by muse, mutect2
- GRIN2B | c.3023A>C p.N1008T | Missense Mutation (SNP) | VAF 60/638 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- GRM5 | c.1886A>T p.Y629F | Missense Mutation (SNP) | VAF 91/362 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HAP1 | c.597G>C p.Q199H | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HDAC6 | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 109/331 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by mutect2, varscan2
- HMCN1 | c.2154A>G p.I718M | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2
- HMCN1 | c.4617A>T p.K1539N | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- HOOK2 | c.2077C>G p.Q693E | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- HOXD9 | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, varscan2
- IQCF1 | c.571G>C p.G191R | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- KDM5A | c.2921T>C p.L974S | Missense Mutation (SNP) | VAF 76/452 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by mutect2, varscan2
- KIF14 | c.2407C>G p.L803V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KRT82 | c.1346T>A p.F449Y | Missense Mutation (SNP) | VAF 105/561 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA3 | c.4667C>G p.P1556R | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMAN1 | c.50T>A p.F17Y | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRK2 | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MSLNL | c.503+1G>T p.X168_splice | Splice Site (SNP) | VAF 15/180 reads (8%) | called by muse, mutect2
- MYLK4 | c.179A>T p.N60I | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); called by muse, mutect2
- NFX1 | c.2468G>A p.G823E | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAX1 | c.746A>G p.N249S | Missense Mutation (SNP) | VAF 92/276 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); called by mutect2, varscan2
- PCDHB13 | c.2122T>C p.F708L | Missense Mutation (SNP) | VAF 42/516 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.076); called by muse, mutect2
- PDE3B | c.2995C>A p.L999M | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHEX | c.987T>A p.H329Q | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.01); called by muse, mutect2
- PKP1 | c.1233A>G p.R411= | Splice Region (SNP) | VAF 51/482 reads (11%) | called by muse, mutect2, varscan2
- POLA1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PSMD14 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RBM38 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2
- RELCH | c.1233G>T p.L411F | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- RTN3 | c.2879T>G p.L960R (on ENST00000377819 / NM_001265589.2; = p.L164R on NM_006054.4) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SAMSN1 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SERINC2 | c.1054C>G p.Q352E (on ENST00000373709 / NM_178865.5; = p.Q356E on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/344 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.511); called by muse, varscan2
- SNX19 | c.2137_2165+1del p.X713_splice | Splice Site (DEL) | VAF 40/214 reads (19%) | called by mutect2, varscan2
- SOSTDC1 | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SUN3 | c.49T>G p.C17G | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.011); called by muse, mutect2
- SYNE1 | c.22318A>C p.I7440L (on ENST00000367255 / NM_182961.4; = p.I7369L on NM_033071.3) | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SZT2 | c.802A>C p.S268R | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.178); called by muse, mutect2
- TBX1 | c.753T>A p.D251E | Missense Mutation (SNP) | VAF 40/455 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2
- TEX15 | c.6014A>T p.Q2005L (on ENST00000256246; = p.Q2388L on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- TJP1 | c.4851del p.P1618Lfs*30 | Frame Shift Del (DEL) | VAF 33/155 reads (21%) | called by mutect2, pindel, varscan2
- ZNF37A | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZNF839 | c.664C>T p.H222Y (on ENST00000558850 / NM_001267827.1; = p.H338Y on NM_018335.5) | Missense Mutation (SNP) | VAF 16/301 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCA1 | c.3294G>A p.G1098= | Silent (SNP) | VAF 175/551 reads (32%) | catalogued as COSV66066988; called by muse, mutect2, varscan2
- ANKH | c.273G>T p.V91= | Silent (SNP) | VAF 57/226 reads (25%) | called by muse, mutect2, varscan2
- ARF3 | c.276C>T p.V92= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as rs778220701; called by muse, mutect2
- ARFGEF2 | c.729A>T p.T243= | Silent (SNP) | VAF 34/270 reads (13%) | called by muse, mutect2, varscan2
- ATP1A3 | c.2982C>A p.A994= (on ENST00000545399 / NM_001256214.2; = p.A981= on NM_152296.5) | Silent (SNP) | VAF 57/221 reads (26%) | called by muse, mutect2, varscan2
- CLEC4A | c.675T>A p.P225= | Silent (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- COLCA2 | c.324G>T p.S108= | Silent (SNP) | VAF 87/343 reads (25%) | catalogued as COSV67695085; called by muse, mutect2, varscan2
- DEFB116 | c.18C>G p.P6= | Silent (SNP) | VAF 65/230 reads (28%) | catalogued as rs765316849, COSV68722433; called by muse, mutect2, varscan2
- DNAH6 | c.990A>T p.G330= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- DOK1 | c.666C>T p.R222= | Silent (SNP) | VAF 56/205 reads (27%) | called by muse, mutect2, varscan2
- ETV2 | c.834T>G p.A278= | Silent (SNP) | VAF 42/155 reads (27%) | called by muse, mutect2, varscan2
- HLTF | c.1731A>G p.E577= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as rs779466153; called by muse, mutect2, varscan2
- LRRC2 | c.876G>T p.G292= | Silent (SNP) | VAF 24/157 reads (15%) | called by muse, mutect2, varscan2
- MC2R | c.597G>A p.L199= | Silent (SNP) | VAF 126/447 reads (28%) | called by muse, mutect2, varscan2
- MINDY3 | c.594A>G p.K198= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- MYRF | c.456G>A p.V152= (on ENST00000278836 / NM_001127392.3; = p.V143= on NM_013279.4) | Silent (SNP) | VAF 32/160 reads (20%) | catalogued as rs1458630791; called by muse, mutect2, varscan2
- POLR1B | c.1818G>A p.L606= | Silent (SNP) | VAF 54/242 reads (22%) | catalogued as COSV54500301; called by muse, mutect2, varscan2
- RFX7 | c.3036T>A p.S1012= (on ENST00000559447 / NM_001368074.1; = p.S1109= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/412 reads (23%) | called by muse, mutect2, varscan2
- RHBDF2 | c.2538C>T p.C846= | Silent (SNP) | VAF 103/187 reads (55%) | catalogued as rs886053470; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMPDL3A | c.1155G>A p.P385= | Silent (SNP) | VAF 96/333 reads (29%) | catalogued as rs770221714, COSV100868659; called by muse, mutect2, varscan2
- SNAPC4 | c.1956G>A p.P652= | Silent (SNP) | VAF 62/127 reads (49%) | catalogued as rs746465888; called by muse, mutect2, varscan2
- SYN1 | c.267G>A p.A89= | Silent (SNP) | VAF 31/128 reads (24%) | called by muse, mutect2, varscan2
- TTC27 | c.1374A>C p.S458= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs1394869377; called by muse, mutect2, varscan2
- ADAMTS17 | c.*26G>C | 3'UTR (SNP) | VAF 137/442 reads (31%) | called by muse, mutect2, varscan2
- AGBL4 | c.34+28715C>A | Intron (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- EIF2B5 | c.321-15C>T | Intron (SNP) | VAF 219/460 reads (48%) | called by muse, mutect2, varscan2
- FAM136A | c.88-436T>G | Intron (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2
- OLFM1 | c.457-467G>T | Intron (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- POU2F1 | c.745-2352C>A | Intron (SNP) | VAF 8/201 reads (4%) | catalogued as rs1260702344; called by muse, mutect2
- UBA1 | c.1939-56G>A | Intron (SNP) | VAF 117/413 reads (28%) | called by muse, mutect2, varscan2
- VCX3B | c.-45C>A | 5'UTR (SNP) | VAF 73/356 reads (21%) | catalogued as rs757799636; called by muse, mutect2, varscan2
- VPS13D | c.8551+12C>T | Intron (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- VPS26C | chr21:37221110 C>A | 3'Flank (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ZIC4 | c.-16+910A>T | Intron (SNP) | VAF 86/299 reads (29%) | called by muse, mutect2, varscan2
